Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8259, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8259-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Prostate gland, radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 23.8 grams.
3. Tumor quantitation: Malignancy is identified in the left lobe only and accounts for less than 5% of the total prostate volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Not identified.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status:

1. No lymph nodes received.

Other:

1. Other significant findings: No prior material for review and comparison is identified in our files.
2. pTNM stage: pT2a, NX.

Electronic Signature: [REDACTED]

COMMENTS:

This case has been reviewed in intradepartmental consultation and as part of the Department's Quality Review Program by Dr [REDACTED] who is in agreement with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single formalin filled container labeled with the patient's name, [REDACTED] and "prostate" and consists of a 23.8 gm, 3.8 x 2.7 x 2.5 cm prostate received with attached bilateral adnexa which has overall dimensions of 3.5 x 2.5 x 0.7 cm. The prostate is pink-tan and shaggy and is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a 3.0 x 1.5 x 1.5 cm, ill defined, tan-orange mass involving the posterior quadrants. This mass approaches to within 0.2 cm of the inked capsule and is present at the prostate/seminal vesicle junction. Gross extension of this lesion into the seminal vesicle is not appreciated. The remainder of the cut surface is pink-tan and focally cystic with diffuse periurethral nodularity. Additional masses or calculi are not identified. Representative sections are submitted in cassettes 1-18 labeled [REDACTED] designated as follows: 1 right prostate/seminal vesicle junction; 2 left prostate/seminal vesicle junction; 3-4 apical margin, perpendicular; 5-6 base margin, perpendicular; 7-9 right anterior, apex to base; 10-12 right posterior, apex to base; 13-15 left anterior, apex to base; 16-18 left posterior, apex to base. Additionally, a yellow-green and blue cassette are submitted for [REDACTED] research, each labeled [REDACTED].

Source: NCI Genomic Data Commons file 6f0ec876-a5d7-4909-a9a0-836d0b97a4b0 (TCGA-HC-8259.E53C1322-0854-4AE8-B087-3DDD3712DF56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).